Somatic mutation profile of tumor specimen TARGET-30-PARACR-01A (aliquot TARGET-30-PARACR-01A-01D) from TARGET case TARGET-30-PARACR, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.3 years (1,191 days).
Specimen TARGET-30-PARACR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dde26839-0ffb-4b69-9e28-af4c72448e24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARACR-10A (Blood Derived Normal), aliquot TARGET-30-PARACR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/687bdd0d-2935-4ded-9023-b0faa030f720

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.2290G>T p.D764Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52639131; called by muse, mutect2, varscan2
- DGKA | c.1770C>A p.S590R | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); catalogued as COSV59386198; called by muse, mutect2, varscan2
- DOCK3 | c.4489G>C p.E1497Q | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV56523346; called by muse, mutect2, varscan2
- DPYSL5 | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56512294, COSV99982477; called by muse, mutect2, varscan2
- EGR1 | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV53519589; called by muse, mutect2, varscan2
- ENPEP | c.2777A>G p.E926G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as COSV54451638; called by muse, mutect2, varscan2
- GSTA3 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV52980621; called by muse, mutect2, varscan2
- MYF5 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV57355259; called by muse, mutect2, varscan2
- NAPEPLD | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58522406; called by muse, mutect2, varscan2
- NPHP1 | c.1030C>A p.Q344K (on ENST00000393272 / NM_207181.4; = p.Q345K on NM_000272.5) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV57208862; called by mutect2, varscan2
- PSMG2 | c.112A>C p.T38P | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50866773; called by muse, mutect2, varscan2
- TCHH | c.3904G>T p.E1302* | Nonsense Mutation (SNP) | VAF 60/290 reads (21%) | catalogued as COSV64275074; called by muse, mutect2, varscan2
- TMEM104 | c.724T>C p.W242R | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59109676; called by muse, mutect2, varscan2
- TSKS | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs74433426, COSV55875440; called by muse, mutect2, varscan2
- ZNF749 | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); catalogued as COSV61946233; called by muse, mutect2, varscan2
- MBNL3 | c.623dup p.S209Efs*2 | Frame Shift Ins (INS) | VAF 56/96 reads (58%) | called by mutect2, pindel, varscan2
- SYCP1 | c.2387C>T p.T796I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TESPA1 | c.1559A>G p.D520G (on ENST00000316577 / NM_001098815.3; = p.D382G on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2
- ZNF138 | c.531C>A p.C177* (on ENST00000307355 / NM_001367572.1; = p.C151* on NM_006524.4) | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- CCDC54 | c.660G>T p.L220= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV53758779; called by muse, mutect2, varscan2
- FILIP1L | c.3271C>A p.R1091= (on ENST00000354552 / NM_182909.3; = p.R851= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/243 reads (7%) | catalogued as COSV58777099; called by muse, mutect2
- MED12L | c.996C>A p.P332= | Silent (SNP) | VAF 39/209 reads (19%) | catalogued as COSV56380197; called by muse, mutect2, varscan2
- NCOA4 | c.1279C>T p.L427= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs1554921080; called by muse, mutect2
- NOP9 | c.150T>C p.A50= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs770234990, COSV55384209, COSV55385037, COSV55385547; called by muse, varscan2
- PRKACG | c.243G>T p.V81= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV55248638, COSV99599840; called by muse, mutect2, varscan2
- RNLS | c.909G>A p.A303= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs748732978, COSV64264426; called by muse, mutect2, varscan2
